Somatic mutation profile of tumor specimen TARGET-15-SJMPAL041117-09A.1 (aliquot TARGET-15-SJMPAL041117-09A.1-01D) from TARGET case TARGET-15-SJMPAL041117, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.1 years (5,523 days).
Specimen TARGET-15-SJMPAL041117-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0654c15-244c-4cf9-b4e5-bd23c5587545.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL041117-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL041117-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a0bc249-aea3-486e-83e0-9209e13f75a4

The open-access MAF lists 39 somatic variants for this specimen: 29 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 7, In Frame Del 2, In Frame Ins 2, Intron 2, Frame Shift Ins 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 44/220 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.13361G>A p.R4454H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1280212847, COSV68946313; called by muse, mutect2, varscan2
- C6 | c.1798C>T p.R600C | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs756691542, COSV54705309; called by muse, mutect2, varscan2
- CACNA1E | c.6856C>T p.R2286W (on ENST00000367573 / NM_001205293.3; = p.R2243W on NM_000721.4) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.928); catalogued as rs762766720, COSV62391040; ClinVar: uncertain significance; called by mutect2, varscan2
- CADM3 | c.541G>A p.E181K (on ENST00000368125 / NM_001127173.3; = p.E215K on NM_021189.5) | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.771); catalogued as rs1325982988; called by muse, mutect2, varscan2
- COL6A1 | c.2941C>A p.P981T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.903); catalogued as rs1569519253, COSV100720193; ClinVar: uncertain significance; called by muse, mutect2
- ERG | c.1109A>G p.D370G (on ENST00000398919 / NM_001243428.1; = p.D346G on NM_004449.4) | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55729043; called by muse, mutect2, varscan2
- FAM47A | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60500739; called by muse, mutect2, varscan2
- HRNR | c.1483G>A p.G495S | Missense Mutation (SNP) | VAF 54/292 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs369964728; called by muse, mutect2, varscan2
- IKBKE | c.1195G>A p.V399I | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs782392890; called by muse, mutect2, varscan2
- PCDHA1 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.052); catalogued as rs1446677911, COSV65374909; called by muse, mutect2, varscan2
- PCDHGA2 | c.2128G>A p.V710M | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.133); catalogued as COSV99541963; called by muse, mutect2, varscan2
- PREX1 | c.4601G>T p.R1534L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV100906698; called by muse, mutect2, varscan2
- RB1CC1 | c.2638G>A p.G880R | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs769839464; called by mutect2, varscan2
- SLITRK5 | c.2711C>A p.P904Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as COSV100280821, COSV61526165; called by muse, mutect2
- THBS4 | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as rs376939207; called by muse, mutect2, varscan2
- C3orf62 | c.404G>T p.R135I | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.976); called by muse, varscan2
- CREBBP | c.3838_3839insGGGGG p.F1280Wfs*35 | Frame Shift Ins (INS) | VAF 39/172 reads (23%) | called by mutect2, pindel, varscan2
- KIAA0825 | c.2394_2398delinsCCGAC p.Q798_K800delinsHRQ | Missense Mutation (ONP) | VAF 10/48 reads (21%) | called by pindel, varscan2*
- NSD3 | c.507_508insATGAG p.S170Mfs*10 | Frame Shift Ins (INS) | VAF 20/86 reads (23%) | called by mutect2, varscan2
- POU4F1 | c.963_964insTCTTCC p.N321_M322insSS | In Frame Ins (INS) | VAF 8/52 reads (15%) | called by mutect2, pindel, varscan2
- PRPF40A | c.1475_1477del p.E492del | In Frame Del (DEL) | VAF 16/70 reads (23%) | called by pindel, varscan2
- SERBP1 | c.1015G>T p.V339F (on ENST00000370995 / NM_001018067.2; = p.V318F on NM_015640.4) | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.675); called by muse, mutect2
- TCF20 | c.1756G>T p.A586S | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.027); called by muse, mutect2
- TSC22D2 | c.1630_1631insCCCCAAGCC p.S543_H544insPPS | In Frame Ins (INS) | VAF 15/75 reads (20%) | called by mutect2, pindel, varscan2
- TTLL3 | c.1522C>T p.P508S | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- VPS13C | c.244A>G p.T82A | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by muse, mutect2
- WDFY3 | c.7555_7557del p.E2519del | In Frame Del (DEL) | VAF 23/95 reads (24%) | called by pindel, varscan2
- ZNF106 | c.1864G>T p.A622S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRL3 | c.1437G>A p.P479= (on ENST00000506720 / NM_001322402.2; = p.P411= on NM_015236.6) | Silent (SNP) | VAF 26/142 reads (18%) | catalogued as rs147936284; called by muse, mutect2, varscan2
- ATP7B | c.1830G>A p.P610= | Silent (SNP) | VAF 38/139 reads (27%) | catalogued as rs375689672; ClinVar: likely benign; called by muse, mutect2, varscan2
- BPIFB4 | c.378C>T p.A126= | Silent (SNP) | VAF 33/148 reads (22%) | catalogued as rs772687337, COSV64951085; called by muse, mutect2, varscan2
- ENTPD2 | c.939G>T p.L313= | Silent (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- FAM167B | c.411C>A p.A137= | Silent (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- MYO15B | c.7245C>T p.D2415= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs1240821087; called by muse, mutect2, varscan2
- ZNF131 | c.612T>C p.G204= | Silent (SNP) | VAF 18/75 reads (24%) | called by muse, mutect2, varscan2
- BHLHE22 | chr8:64576542 C>T | 5'Flank (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- ITGAD | c.859-31C>A | Intron (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- RIMS1 | c.1679-20566C>T | Intron (SNP) | VAF 14/49 reads (29%) | catalogued as rs1348116165; called by muse, mutect2, varscan2
